Somatic mutation profile of cancer-model specimen HCM-BROD-0043-C16-85B (Mixed Adherent Suspension, passage 7; aliquot HCM-BROD-0043-C16-85B-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0043-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.7 years (25,092 days).
Specimen HCM-BROD-0043-C16-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27d3098e-2b4f-4ff4-bc8d-43107a059235.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0043-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0043-C16-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8fe15f5-f662-4ad7-82b7-3926eb5dde13

The open-access MAF lists 302 somatic variants for this specimen: 234 protein-altering or splice-affecting, 57 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 57, Intron 7, Nonsense Mutation 7, Frame Shift Del 5, 5'UTR 3, Splice Region 2, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 79/79 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs876659443, CM110119, COSV64289131, COSV64291926, COSV64310633; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.379T>C p.S127P | Missense Mutation (SNP) | VAF 275/277 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2, varscan2
- ACTL9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.324); catalogued as rs782524837, COSV61005237; called by muse, mutect2, varscan2
- AJAP1 | c.536A>C p.E179A | Missense Mutation (SNP) | VAF 99/981 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.63); catalogued as COSV65449977, COSV65455371; called by muse, mutect2, varscan2
- ANKMY1 | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 199/625 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369197129, COSV99801171; called by muse, mutect2, varscan2
- ANKRD62 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs552494998; called by muse, mutect2, varscan2
- ANTXRL | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 142/302 reads (47%) | SIFT tolerated (0.36); catalogued as rs782774064; called by muse, mutect2, varscan2
- AP1M2 | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 148/355 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV51567568; called by muse, mutect2, varscan2
- AP4E1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.082); catalogued as COSV99956702; called by muse, mutect2, varscan2
- ATP9A | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 110/639 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1435810983; called by muse, varscan2
- AZGP1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 463/912 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs751369711; called by muse, mutect2, varscan2
- BAZ1A | c.38A>C p.K13T | Missense Mutation (SNP) | VAF 605/783 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs775641660; called by muse, mutect2, varscan2
- BRIX1 | c.392C>G p.S131* | Nonsense Mutation (SNP) | VAF 69/365 reads (19%) | catalogued as COSV100384447; called by muse, mutect2, varscan2
- CCDC138 | c.1799T>G p.L600R | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1344055922; called by muse, mutect2, varscan2
- CDH1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 121/542 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1221633501; called by muse, mutect2, varscan2
- CLCN1 | c.2786C>A p.T929N | Missense Mutation (SNP) | VAF 124/759 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.1); catalogued as rs777708543; called by muse, varscan2
- CLK4 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 63/400 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60317755; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 131/223 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNBD2 | c.1460A>C p.K487T (on ENST00000373973 / NM_001365709.1; = p.K483T on NM_080834.4) | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.122); catalogued as COSV100839133; called by muse, mutect2, varscan2
- CRB2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 165/362 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100749575; called by muse, mutect2, varscan2
- DSP | c.3514G>C p.E1172Q | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV65796846; called by muse, mutect2, varscan2
- EP300 | c.5597C>T p.P1866L | Missense Mutation (SNP) | VAF 91/567 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs763290593, COSV54349009; called by muse, mutect2, varscan2
- FAM174A | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as rs779059148, COSV100444659; called by muse, varscan2
- FLT4 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 287/671 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs1448080273; called by muse, mutect2, varscan2
- FOXL2 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 440/2274 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV57728109; called by muse, mutect2, varscan2
- HFM1 | c.804G>A p.P268= | Splice Region (SNP) | VAF 45/90 reads (50%) | catalogued as rs755797245, COSV54034143; called by muse, mutect2, varscan2
- ITGB6 | c.476T>G p.L159R | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558188627; called by muse, mutect2, varscan2
- KCNH1 | c.857T>G p.L286R | Missense Mutation (SNP) | VAF 61/620 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV55069756, COSV55079390, COSV99661871; called by muse, mutect2
- KDM5B | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 127/402 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.682); catalogued as rs148627688; called by muse, mutect2, varscan2
- KLC1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 236/676 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs926694130, COSV55808068; called by muse, mutect2, varscan2
- KNL1 | c.1727G>A p.S576N (on ENST00000346991 / NM_170589.5; = p.S550N on NM_144508.5) | Missense Mutation (SNP) | VAF 209/315 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs956827247; called by muse, mutect2, varscan2
- KRTAP19-3 | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 123/240 reads (51%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs749248768; called by muse, mutect2, varscan2
- LARP1 | c.2431G>C p.D811H (on ENST00000518297 / NM_033551.3; = p.D734H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/328 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100303665; called by muse, mutect2
- LRIG1 | c.1886A>G p.Q629R | Missense Mutation (SNP) | VAF 225/4406 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1462792998; called by muse, mutect2
- LRRC7 | c.2659C>T p.P887S (on ENST00000651989 / NM_001370785.2; = p.P854S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 172/331 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267598707; called by muse, mutect2, varscan2
- MAVS | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs749871584, COSV63926481; called by muse, mutect2, varscan2
- MC4R | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs141148170; called by muse, mutect2, varscan2
- MLH1 | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 100/349 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs876659787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPP4 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100206696; called by muse, mutect2, varscan2
- NCOA7 | c.2767G>A p.D923N | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV57654946; called by muse, mutect2, varscan2
- NEXMIF | c.971A>C p.K324T | Missense Mutation (SNP) | VAF 141/244 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50168203, COSV99281502; called by muse, mutect2, varscan2
- NFU1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 152/589 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs750378027, COSV100361370; called by muse, mutect2, varscan2
- NPB | c.76T>C p.Y26H | Missense Mutation (SNP) | VAF 55/546 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs953011735; called by muse, mutect2, varscan2
- NR3C1 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.131); catalogued as COSV99196203; called by muse, mutect2, varscan2
- NWD1 | c.4072A>G p.T1358A | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1479018583; called by muse, mutect2, varscan2
- OBSCN | c.12206A>C p.K4069T | Missense Mutation (SNP) | VAF 15/349 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.038); catalogued as COSV52738901; called by muse, mutect2
- OR5L2 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 218/525 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV65723759; called by muse, mutect2, varscan2
- OR8K1 | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 202/478 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.167); catalogued as COSV54401231, COSV54401510; called by muse, mutect2, varscan2
- PARVG | c.668A>G p.K223R | Missense Mutation (SNP) | VAF 144/283 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1447270016; called by muse, mutect2, varscan2
- PAX7 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 103/440 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.634); catalogued as rs370742910; called by muse, mutect2, varscan2
- PCDHA6 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 440/685 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.421); catalogued as COSV65342270; called by muse, mutect2, varscan2
- PIGS | c.541A>T p.I181F | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV52027196; called by muse, mutect2, varscan2
- PPEF2 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1277441879; called by muse, mutect2
- PREX2 | c.3433C>T p.P1145S | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55757881; called by muse, mutect2, varscan2
- PRICKLE2 | c.2296C>G p.R766G (on ENST00000295902; = p.R710G on NM_198859.4) | Missense Mutation (SNP) | VAF 186/1709 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1265364678, COSV55762145, COSV99897981; called by muse, mutect2, varscan2
- PTPN6 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 111/343 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); catalogued as rs782167753, COSV59684032; called by muse, mutect2, varscan2
- RCCD1 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 66/341 reads (19%) | catalogued as rs778888317; called by muse, mutect2, varscan2
- SLC38A8 | c.1276A>G p.S426G | Missense Mutation (SNP) | VAF 270/548 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1409654150; called by muse, mutect2, varscan2
- SLC45A4 | c.649G>C p.D217H (on ENST00000517878 / NM_001286646.2; = p.D166H on NM_001080431.2) | Missense Mutation (SNP) | VAF 185/457 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50142368; called by muse, mutect2, varscan2
- SPART | c.1559T>C p.L520P | Missense Mutation (SNP) | VAF 108/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62084076; called by muse, mutect2, varscan2
- STRA8 | c.250G>A p.A84T (on ENST00000275764; = p.A62T on NM_182489.2) | Missense Mutation (SNP) | VAF 328/329 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as COSV99312166; called by muse, mutect2, varscan2
- SUCLG2 | c.527A>C p.D176A | Missense Mutation (SNP) | VAF 63/1034 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781757897; called by muse, mutect2
- SYNE1 | c.24485A>T p.K8162M (on ENST00000367255 / NM_182961.4; = p.K8091M on NM_033071.3) | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54911117, COSV54968317; called by muse, mutect2
- TOR1AIP1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs1425717250; called by muse, mutect2
- TRMT10C | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); catalogued as COSV99998174; called by muse, mutect2, varscan2
- UNC5D | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 255/462 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs762892028; called by muse, mutect2, varscan2
- ZDHHC5 | c.36C>A p.S12R | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV54707786; called by muse, mutect2, varscan2
- ZNF316 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 102/862 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV66385084; called by muse, mutect2
- ZSCAN18 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 113/575 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754074982, COSV99559549; called by muse, mutect2, varscan2
- A2M | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2
- ABCA1 | c.5546T>C p.V1849A | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ACP4 | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ADAM17 | c.1268G>A p.C423Y | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY1 | c.1840G>C p.V614L | Missense Mutation (SNP) | VAF 220/443 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADGRL3 | c.3883A>G p.T1295A | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AEBP1 | c.828del p.K277Rfs*15 | Frame Shift Del (DEL) | VAF 316/820 reads (39%) | called by mutect2, pindel, varscan2
- AGAP6 | c.1669C>G p.L557V (on ENST00000374056 / NM_001365867.1; = p.L580V on NM_001077665.2) | Missense Mutation (SNP) | VAF 150/613 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AKAP17A | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 143/370 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AKAP6 | c.4393T>A p.F1465I | Missense Mutation (SNP) | VAF 363/460 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- AOPEP | c.2103G>T p.E701D (on ENST00000375315 / NM_001193329.1; = p.E602D on NM_032823.5) | Missense Mutation (SNP) | VAF 114/261 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ARHGAP20 | c.3437G>C p.G1146A | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARMC10 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 46/271 reads (17%) | called by muse, mutect2, varscan2
- ASPG | c.282_283dup p.C95Ffs*75 | Frame Shift Ins (INS) | VAF 519/880 reads (59%) | called by mutect2, pindel, varscan2
- ATXN2L | c.2158G>A p.G720R | Missense Mutation (SNP) | VAF 140/245 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CACNA1S | c.4451A>C p.E1484A | Missense Mutation (SNP) | VAF 180/532 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASR | c.2431A>G p.T811A (on ENST00000490131; = p.T888A on NM_000388.4) | Missense Mutation (SNP) | VAF 231/469 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CATSPERG | c.1487T>C p.L496P | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC168 | c.14315C>G p.P4772R | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CCDC168 | c.8913A>C p.K2971N | Missense Mutation (SNP) | VAF 110/439 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- CCDC168 | c.7137A>G p.I2379M | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CDH1 | c.495A>T p.E165D | Missense Mutation (SNP) | VAF 311/311 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKL5 | c.137A>C p.D46A | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CENPJ | c.3854A>G p.N1285S | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CEP128 | c.338A>C p.D113A | Missense Mutation (SNP) | VAF 13/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- CEP250 | c.5201A>C p.K1734T | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP47 | c.1909T>A p.Y637N | Missense Mutation (SNP) | VAF 67/98 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CLIC5 | c.671A>T p.N224I (on ENST00000185206 / NM_001370649.1; = p.N65I on NM_016929.5) | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CLSTN2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 38/714 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2
- CNGA3 | c.687A>C p.Q229H | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- COL24A1 | c.3557C>A p.P1186H | Missense Mutation (SNP) | VAF 185/269 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL4A2 | c.2421C>A p.F807L | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.086); called by muse, mutect2
- COL4A6 | c.4867T>C p.S1623P | Missense Mutation (SNP) | VAF 180/327 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPRS | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 51/251 reads (20%) | called by muse, mutect2, varscan2
- CPB2 | c.571T>C p.C191R | Missense Mutation (SNP) | VAF 96/316 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CROT | c.1709G>C p.R570T | Missense Mutation (SNP) | VAF 41/286 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CTIF | c.876C>A p.S292R | Missense Mutation (SNP) | VAF 205/616 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DAB1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 201/302 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DAXX | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 148/875 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- DDX19B | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 70/475 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- DENND4A | c.298del p.T101Qfs*13 | Frame Shift Del (DEL) | VAF 65/214 reads (30%) | called by mutect2, pindel, varscan2
- DENND4C | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 170/271 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX15 | c.2068A>G p.R690G | Missense Mutation (SNP) | VAF 146/204 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIPK1C | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 130/403 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DLG4 | c.787+6A>G | Splice Region (SNP) | VAF 144/570 reads (25%) | called by muse, mutect2, varscan2
- DLGAP4 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 160/518 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAAF1 | c.1074T>G p.S358R | Missense Mutation (SNP) | VAF 208/451 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH12 | c.3368T>C p.V1123A (on ENST00000351747; = p.V1146A on NM_001366028.2) | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH2 | c.11330G>A p.G3777D | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- DNHD1 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 203/203 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNTT | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 117/193 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- DPF2 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DRAM2 | c.287T>G p.L96R | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DRC1 | c.356G>T p.R119M | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DSEL | c.1091A>G p.N364S | Missense Mutation (SNP) | VAF 141/411 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DVL3 | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 256/909 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- EIF2B5 | c.573_575del p.M191del (on ENST00000647909; = p.M183del on NM_003907.3) | In Frame Del (DEL) | VAF 85/686 reads (12%) | called by pindel, varscan2
- ENTPD3 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERICH6B | c.1508A>C p.N503T | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ERICH6B | c.1196A>C p.K399T | Missense Mutation (SNP) | VAF 97/367 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- FER1L5 | c.2585G>C p.R862T (on ENST00000623019; = p.R867T on NM_001293083.2) | Missense Mutation (SNP) | VAF 99/425 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGGY | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 143/300 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FMNL3 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FRMPD4 | c.590A>C p.N197T | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- GLB1 | c.1510A>G p.N504D | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPC5 | c.1007A>T p.K336I | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- HACE1 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR6 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- HELZ2 | c.7202T>A p.L2401Q (on ENST00000467148 / NM_001037335.2; = p.L1832Q on NM_033405.3) | Missense Mutation (SNP) | VAF 91/896 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- HMCN1 | c.12671T>C p.L4224P | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HMX1 | c.55T>G p.F19V | Missense Mutation (SNP) | VAF 381/573 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HOXB8 | c.43A>C p.T15P | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.047); called by mutect2, varscan2
- HYDIN | c.2917C>A p.P973T | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGF1R | c.3761A>C p.K1254T | Missense Mutation (SNP) | VAF 102/469 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- INSYN2B | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 126/466 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KBTBD8 | c.1213A>G p.R405G | Missense Mutation (SNP) | VAF 59/995 reads (6%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.991); called by muse, mutect2
- KCNC3 | c.1949A>C p.Q650P | Missense Mutation (SNP) | VAF 81/494 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- KIDINS220 | c.1633T>G p.F545V | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT2 | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 77/274 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- LARP7 | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCE1F | c.354C>G p.C118W | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LIN9 | c.692G>A p.R231K (on ENST00000366808 / NM_001270410.2; = p.R176K on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- LMOD3 | c.679T>G p.F227V | Missense Mutation (SNP) | VAF 53/905 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2
- LOXHD1 | c.4274A>C p.K1425T | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- LRFN2 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 74/638 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LTV1 | c.1372A>T p.R458W | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LZTS3 | c.2000G>A p.R667H (on ENST00000329152; = p.R621H on NM_001282533.2) | Missense Mutation (SNP) | VAF 99/370 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MAGEC3 | c.776C>A p.T259N | Missense Mutation (SNP) | VAF 100/222 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MCRS1 | c.974A>C p.K325T | Missense Mutation (SNP) | VAF 136/496 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MCTP2 | c.1141A>C p.K381Q | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MLXIPL | c.505T>G p.Y169D | Missense Mutation (SNP) | VAF 39/608 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MNDA | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MSMO1 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MTMR2 | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYCBP2 | c.3546A>C p.Q1182H (on ENST00000357337; = p.Q1220H on NM_015057.5) | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MYF5 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 117/520 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO18B | c.4382A>G p.E1461G | Missense Mutation (SNP) | VAF 139/255 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NRCAM | c.3187G>A p.V1063I | Missense Mutation (SNP) | VAF 214/426 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NRTN | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 173/386 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUDT7 | c.400del p.A134Pfs*58 | Frame Shift Del (DEL) | VAF 99/463 reads (21%) | called by mutect2, pindel, varscan2
- OR2AP1 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2T3 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 88/444 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, varscan2
- OR5H1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PACS1 | c.2031C>G p.D677E | Missense Mutation (SNP) | VAF 128/510 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by mutect2, varscan2
- PCDHB13 | c.2244C>G p.S748R | Missense Mutation (SNP) | VAF 200/339 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PCLO | c.15026G>A p.G5009E | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCM1 | c.4613C>G p.S1538* | Nonsense Mutation (SNP) | VAF 142/306 reads (46%) | called by muse, mutect2, varscan2
- PHF20 | c.2856A>C p.E952D | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PLIN5 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 209/557 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLOD3 | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 274/665 reads (41%) | called by muse, mutect2, varscan2
- PNKD | c.920_932del p.E307Gfs*33 | Frame Shift Del (DEL) | VAF 53/286 reads (19%) | called by mutect2, pindel, varscan2
- PPFIBP1 | c.2554T>G p.L852V (on ENST00000318304 / NM_177444.3; = p.L846V on NM_003622.4) | Missense Mutation (SNP) | VAF 102/283 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRRC2B | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 185/376 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- PSMB6 | c.432G>C p.Q144H | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPN13 | c.5854G>C p.D1952H (on ENST00000411767 / NM_080683.3; = p.D1933H on NM_006264.3) | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PTPRT | c.2107A>T p.I703F | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PYDC2 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 46/433 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM4B | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 119/469 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RNF5 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 106/1024 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- SACS | c.4054A>G p.S1352G | Missense Mutation (SNP) | VAF 77/363 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SCAPER | c.2230A>G p.K744E | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- SEMA5B | c.2448G>T p.R816S | Missense Mutation (SNP) | VAF 139/854 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- SH3PXD2A | c.2686C>G p.L896V (on ENST00000369774 / NM_001365079.1; = p.L868V on NM_014631.2) | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SKIV2L | c.1751C>A p.S584* | Nonsense Mutation (SNP) | VAF 134/1626 reads (8%) | called by muse, mutect2
- SLC25A12 | c.1565T>C p.L522P | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC6A16 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- SLCO6A1 | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SLITRK4 | c.1673T>G p.L558R | Missense Mutation (SNP) | VAF 136/258 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- SPINT3 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 96/454 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTAN1 | c.829T>G p.L277V | Missense Mutation (SNP) | VAF 114/239 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SRGAP2 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SSC4D | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 101/1011 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- STAB1 | c.1790C>T p.T597I | Missense Mutation (SNP) | VAF 297/297 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SULT1C2 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 122/386 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SYN3 | c.609C>A p.S203R | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYTL5 | c.1555T>G p.F519V | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TBC1D4 | c.1347G>C p.Q449H | Missense Mutation (SNP) | VAF 109/468 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TCF7L2 | c.226del p.R76Efs*32 | Frame Shift Del (DEL) | VAF 128/254 reads (50%) | called by mutect2, pindel, varscan2
- TEKT1 | c.65A>C p.N22T | Missense Mutation (SNP) | VAF 128/375 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- THAP3 | c.718T>G p.*240Gext*82 (on ENST00000054650 / NM_001195753.1; = p.*239Gext*82 on NM_001195752.1) | Nonstop Mutation (SNP) | VAF 135/186 reads (73%) | called by muse, mutect2, varscan2
- THBS1 | c.2051G>A p.G684D | Missense Mutation (SNP) | VAF 105/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC2 | c.2202G>T p.L734F | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TMPRSS15 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 170/171 reads (99%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TREX1 | c.689G>A p.R230K (on ENST00000625293 / NM_033629.6; = p.R220K on NM_007248.5) | Missense Mutation (SNP) | VAF 176/461 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM60 | c.487A>C p.I163L | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPV1 | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 119/452 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, varscan2
- TTLL12 | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 120/567 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TTN | c.26709T>G p.D8903E (on ENST00000591111; = p.D7976E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/283 reads (33%) | PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TTN | c.1060T>G p.S354A | Missense Mutation (SNP) | VAF 154/368 reads (42%) | PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TTPA | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 305/714 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- UBE4A | c.2732T>G p.L911R (on ENST00000252108 / NM_001204077.2; = p.L918R on NM_004788.4) | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UPK3B | c.742C>A p.L248I (on ENST00000257632; = p.A219= on NM_001347684.2) | Missense Mutation (SNP) | VAF 100/660 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- VCX | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 180/514 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.094); called by muse, varscan2
- VCX3A | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, varscan2
- VEGFD | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 164/303 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VPS13A | c.1016T>A p.L339H | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- VWA8 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 103/467 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- VWC2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 1018/1019 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR46 | c.55C>G p.Q19E | Missense Mutation (SNP) | VAF 141/940 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WDR92 | c.104C>G p.T35S | Missense Mutation (SNP) | VAF 145/560 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- WRAP53 | c.785G>C p.G262A | Missense Mutation (SNP) | VAF 191/636 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZFP57 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 244/1276 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ZHX3 | c.2655G>T p.E885D | Missense Mutation (SNP) | VAF 117/360 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- ZNF568 | c.588A>C p.K196N | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- AKAP6 | c.4803T>G p.T1601= | Silent (SNP) | VAF 478/612 reads (78%) | catalogued as COSV99797910; called by muse, mutect2, varscan2
- ALG10B | c.1263T>G p.P421= | Silent (SNP) | VAF 71/247 reads (29%) | called by muse, mutect2, varscan2
- C10orf67 | c.1560T>A p.L520= | Silent (SNP) | VAF 49/206 reads (24%) | called by muse, mutect2, varscan2
- C10orf90 | c.534G>A p.P178= | Silent (SNP) | VAF 290/379 reads (77%) | catalogued as rs571656172; called by muse, mutect2, varscan2
- CAMKK1 | c.666T>G p.A222= | Silent (SNP) | VAF 93/328 reads (28%) | called by muse, mutect2, varscan2
- CCDC169 | c.582T>C p.S194= | Silent (SNP) | VAF 63/283 reads (22%) | catalogued as rs1397698905; called by muse, mutect2, varscan2
- CMYA5 | c.1152C>T p.D384= | Silent (SNP) | VAF 95/204 reads (47%) | called by muse, mutect2, varscan2
- COL4A5 | c.774A>C p.G258= | Silent (SNP) | VAF 88/159 reads (55%) | called by muse, mutect2, varscan2
- COL6A5 | c.7365A>G p.E2455= (on ENST00000312481; = p.E2451= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/332 reads (15%) | called by muse, mutect2, varscan2
- DLL3 | c.42G>C p.V14= | Silent (SNP) | VAF 83/480 reads (17%) | called by muse, mutect2, varscan2
- DNA2 | c.1674T>G p.T558= | Silent (SNP) | VAF 152/290 reads (52%) | called by muse, mutect2, varscan2
- DROSHA | c.1770T>C p.T590= | Silent (SNP) | VAF 32/418 reads (8%) | called by muse, mutect2
- ERICH3 | c.3657T>C p.P1219= | Silent (SNP) | VAF 115/422 reads (27%) | called by muse, mutect2, varscan2
- FAAP24 | c.222G>A p.K74= | Silent (SNP) | VAF 91/237 reads (38%) | called by muse, mutect2, varscan2
- FFAR3 | c.873G>A p.L291= | Silent (SNP) | VAF 44/493 reads (9%) | called by muse, mutect2
- FLG | c.810A>G p.Q270= | Silent (SNP) | VAF 111/476 reads (23%) | called by muse, mutect2, varscan2
- FOXL2 | c.462G>A p.R154= | Silent (SNP) | VAF 149/2554 reads (6%) | catalogued as rs751648653; called by muse, mutect2
- GABRG2 | c.856A>C p.R286= (on ENST00000361925 / NM_001375343.1; = p.R246= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 148/303 reads (49%) | catalogued as COSV62715776; called by muse, mutect2, varscan2
- HDAC7 | c.1239C>T p.G413= (on ENST00000427332; = p.G452= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 240/765 reads (31%) | catalogued as rs1266319555, COSV50349081; called by muse, mutect2, varscan2
- HDAC9 | c.2754C>A p.G918= | Silent (SNP) | VAF 344/431 reads (80%) | catalogued as COSV67768656; called by muse, mutect2, varscan2
- ICE1 | c.4911T>C p.A1637= | Silent (SNP) | VAF 106/534 reads (20%) | catalogued as rs1432513949; called by muse, mutect2, varscan2
- IGHV3-48 | c.291A>C p.S97= | Silent (SNP) | VAF 484/834 reads (58%) | catalogued as rs782021078; called by muse, mutect2, varscan2
- ITGA9 | c.816A>G p.K272= | Silent (SNP) | VAF 110/337 reads (33%) | called by muse, mutect2, varscan2
- KCNB1 | c.2037T>G p.G679= | Silent (SNP) | VAF 70/641 reads (11%) | called by muse, mutect2, varscan2
- KCNH7 | c.1890C>T p.F630= | Silent (SNP) | VAF 153/192 reads (80%) | catalogued as COSV100033700; called by muse, mutect2, varscan2
- KRTAP9-3 | c.150T>C p.T50= | Silent (SNP) | VAF 250/526 reads (48%) | catalogued as COSV66647254; called by muse, mutect2, varscan2
- LDHB | c.963A>G p.A321= | Silent (SNP) | VAF 96/336 reads (29%) | called by muse, mutect2, varscan2
- LOXL2 | c.1311G>A p.L437= | Silent (SNP) | VAF 212/384 reads (55%) | catalogued as rs746826821, COSV66692357; called by muse, mutect2, varscan2
- LTBP2 | c.4041C>T p.N1347= | Silent (SNP) | VAF 116/673 reads (17%) | catalogued as rs772766355, COSV56207222; called by muse, mutect2, varscan2
- NFIL3 | c.624C>T p.C208= | Silent (SNP) | VAF 97/189 reads (51%) | catalogued as COSV52683856; called by muse, mutect2, varscan2
- NRP1 | c.1554G>T p.G518= | Silent (SNP) | VAF 286/855 reads (33%) | catalogued as rs781186851; called by muse, mutect2, varscan2
- OR52N5 | c.501T>G p.P167= | Silent (SNP) | VAF 177/283 reads (63%) | catalogued as COSV57698409; called by muse, mutect2, varscan2
- PDZD2 | c.3963T>A p.A1321= | Silent (SNP) | VAF 162/731 reads (22%) | called by muse, mutect2, varscan2
- POLR1B | c.2217C>T p.T739= | Silent (SNP) | VAF 27/266 reads (10%) | called by muse, mutect2, varscan2
- PSMD4 | c.18T>A p.T6= | Silent (SNP) | VAF 301/506 reads (59%) | called by muse, mutect2, varscan2
- PTPRQ | c.2296T>C p.L766= (on ENST00000616559; = p.L724= on NM_001145026.2) | Silent (SNP) | VAF 146/311 reads (47%) | catalogued as COSV57038322, COSV57057983; called by muse, mutect2, varscan2
- RPRD2 | c.2670T>G p.P890= | Silent (SNP) | VAF 82/352 reads (23%) | called by muse, mutect2, varscan2
- SAMD11 | c.1077C>T p.P359= | Silent (SNP) | VAF 100/1182 reads (8%) | catalogued as rs895034807; called by muse, mutect2
- SCN4A | c.1770C>T p.L590= | Silent (SNP) | VAF 117/365 reads (32%) | called by muse, mutect2, varscan2
- SEC23B | c.942T>G p.S314= | Silent (SNP) | VAF 48/185 reads (26%) | called by muse, mutect2, varscan2
- SELENOW | c.36T>C p.A12= | Silent (SNP) | VAF 106/282 reads (38%) | catalogued as rs1568607822; called by muse, mutect2, varscan2
- SKIV2L | c.915C>T p.F305= | Silent (SNP) | VAF 75/718 reads (10%) | called by muse, mutect2, varscan2
- SLC6A15 | c.387C>T p.S129= | Silent (SNP) | VAF 101/213 reads (47%) | catalogued as rs754406059; called by muse, varscan2
- SPDYE5 | c.594C>G p.A198= | Silent (SNP) | VAF 20/624 reads (3%) | called by muse, mutect2
- SRPK1 | c.225A>G p.L75= | Silent (SNP) | VAF 108/401 reads (27%) | catalogued as rs200925470; called by muse, mutect2, varscan2
- TESK1 | c.1038C>T p.P346= | Silent (SNP) | VAF 211/638 reads (33%) | catalogued as rs139838175; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3204T>C p.A1068= | Silent (SNP) | VAF 107/642 reads (17%) | catalogued as rs373554420; called by muse, mutect2, varscan2
- TRIM24 | c.723G>C p.L241= | Silent (SNP) | VAF 79/381 reads (21%) | catalogued as COSV100631106; called by muse, mutect2, varscan2
- USP13 | c.660C>G p.L220= | Silent (SNP) | VAF 67/579 reads (12%) | called by muse, mutect2, varscan2
- USP34 | c.4245A>G p.S1415= | Silent (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- WASF3 | c.576G>A p.V192= | Silent (SNP) | VAF 76/290 reads (26%) | called by muse, mutect2, varscan2
- WDR87 | c.615C>T p.I205= | Silent (SNP) | VAF 72/332 reads (22%) | called by muse, mutect2, varscan2
- WDR87 | c.246C>T p.L82= | Silent (SNP) | VAF 76/330 reads (23%) | catalogued as rs376020296; called by muse, mutect2, varscan2
- WWOX | c.780A>G p.S260= | Silent (SNP) | VAF 59/303 reads (19%) | catalogued as COSV68373286; called by muse, mutect2, varscan2
- ZBTB14 | c.522T>C p.S174= | Silent (SNP) | VAF 97/330 reads (29%) | called by muse, mutect2, varscan2
- ZNF117 | c.1359T>G p.A453= | Silent (SNP) | VAF 42/476 reads (9%) | catalogued as rs1354754493, COSV51429595; called by muse, mutect2
- ZNF217 | c.1542G>A p.L514= | Silent (SNP) | VAF 64/515 reads (12%) | catalogued as COSV100184688; called by muse, mutect2, varscan2
- ABI3BP | c.1577-7699T>G | Intron (SNP) | VAF 50/296 reads (17%) | called by muse, mutect2, varscan2
- ALDH16A1 | c.-1G>T | 5'UTR (SNP) | VAF 67/408 reads (16%) | called by muse, mutect2, varscan2
- DCAF6 | c.1378+11057A>G | Intron (SNP) | VAF 163/492 reads (33%) | called by muse, mutect2, varscan2
- GRIK2 | c.-252T>G | 5'UTR (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- KAZN | c.227-36165G>A | Intron (SNP) | VAF 48/230 reads (21%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-30841C>T | Intron (SNP) | VAF 84/192 reads (44%) | called by muse, mutect2, varscan2
- NSRP1 | c.114+9779del | Intron (DEL) | VAF 98/238 reads (41%) | called by mutect2, pindel, varscan2
- RGL1 | c.-428C>T | 5'UTR (SNP) | VAF 167/458 reads (36%) | called by muse, mutect2, varscan2
- RHOT1 | c.1739+2908T>G | Intron (SNP) | VAF 23/355 reads (6%) | called by muse, mutect2
- XIST | n.8964T>C | RNA (SNP) | VAF 69/118 reads (58%) | called by muse, mutect2, varscan2
- ZNF680 | c.254-3910G>C | Intron (SNP) | VAF 161/189 reads (85%) | catalogued as COSV59019080; called by muse, mutect2, varscan2
